Gene-level copy-number profile of tumor specimen TCGA-AR-A24H-01A from TCGA case TCGA-AR-A24H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.8 years (24,046 days).
Specimen TCGA-AR-A24H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.95021181-8971-4d62-acf9-9a7bd1b960f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A24H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc7bc12b-cce3-4ebe-8a00-3a28dcb30ad0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 2,086; copy number 2: 11,291; copy number 3: 16,633; copy number 4: 17,205; copy number 5: 6,965; copy number 6: 3,131; copy number 7: 816; copy number 8: 744; copy number 9: 730; copy number 10: 187.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A24H-01A-11D-A166-01): tumor purity 0.75, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:31,846,713–32,954,401, 19 genes (within-gene range 0–2): FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 917 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:115,408,496–145,066,685, 507 genes, copy number 9–10 (broad region; genes not listed).
- chr10:933,026–1,737,525, 13 genes, copy number 9: AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1.
- chr12:75,040,077–98,735,433, 343 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:98,794,485–99,105,011, 4 genes, copy number 9: AC008126.1, AC069437.1, RNA5SP366, AC117377.1.
- chr13:108,480,226–111,344,249, 50 genes, copy number 9: HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1, TEX29.

Autosomal genes at a single copy (total copy number 1): 709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
